Somatic mutation profile of tumor specimen TCGA-XF-A9T6-01A (aliquot TCGA-XF-A9T6-01A-11D-A42E-08) from TCGA case TCGA-XF-A9T6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 88.2 years (32,207 days).
Specimen TCGA-XF-A9T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac40e0c7-8b10-48a2-a30a-5b574672732c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T6-10A (Blood Derived Normal), aliquot TCGA-XF-A9T6-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35bd5e25-79d3-4103-ad15-dcff4dd5f4f7

The open-access MAF lists 362 somatic variants for this specimen: 270 protein-altering or splice-affecting, 82 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 82, Nonsense Mutation 12, Splice Site 10, Frame Shift Del 8, Intron 5, In Frame Del 5, Frame Shift Ins 3, Splice Region 3, Translation Start Site 3, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1333-1G>A p.X445_splice | Splice Site (SNP) | VAF 39/65 reads (60%) | hotspot (GDC flag); catalogued as CD030602, CS044092, COSV57294792; called by muse, mutect2, varscan2
- TP53 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253942, CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- A2M | c.2910T>G p.Y970* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100588936; called by muse, mutect2, varscan2
- ABCA6 | c.2063A>C p.N688T | Missense Mutation (SNP) | VAF 71/283 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV52635320; called by muse, mutect2, varscan2
- ABCC11 | c.2522G>C p.R841P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV62321119, COSV62322128; called by muse, mutect2, varscan2
- ABCG2 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV52942759; called by muse, mutect2, varscan2
- ABL1 | c.1883C>G p.P628R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.314); catalogued as COSV59324189; called by muse, varscan2
- ACOT4 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58335349; called by muse, mutect2, varscan2
- ACTL7B | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65926818; called by muse, mutect2, varscan2
- ADAMTSL2 | c.241T>C p.S81P | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV63203129; called by muse, mutect2, varscan2
- ADGRB3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 65/88 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369405391, COSV65394023; called by muse, mutect2, varscan2
- AGBL5 | c.2620G>T p.V874F | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64078983; called by muse, mutect2, varscan2
- AKAP9 | c.8744A>C p.H2915P (on ENST00000359028; = p.H2891P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV62338107; called by muse, mutect2, varscan2
- AL031681.2 | c.3128C>T p.T1043I | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs770260156, COSV64227774; called by muse, mutect2, varscan2
- ALDH1A3 | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1408365041, COSV60900723; called by muse, mutect2, varscan2
- ANKRD30A | c.271_278del p.F91Rfs*7 (on ENST00000611781; = p.F35Rfs*7 on NM_052997.2) | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as COSV64603255; called by mutect2, pindel, varscan2
- ANO1 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.085); catalogued as COSV62443130; called by muse, mutect2, varscan2
- APC | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.13); catalogued as COSV57322599, COSV57324467; called by muse, mutect2, varscan2
- ARHGAP44 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs770184726, COSV52388798; called by muse, mutect2, varscan2
- ARNT | c.1711G>C p.G571R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as COSV62229583; called by muse, mutect2, varscan2
- ARPC2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs1433485062, COSV55283528; called by muse, mutect2, varscan2
- ASAH2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270085; called by muse, mutect2, varscan2
- ASXL2 | c.2590A>C p.N864H | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV55453001; called by muse, mutect2, varscan2
- ASXL2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55453009; called by muse, mutect2, varscan2
- ATP11C | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1485593813, COSV59559200; called by muse, mutect2, varscan2
- ATP2B3 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1557010446, CM156865, COSV54839891; called by muse, mutect2, varscan2
- ATP7A | c.3106C>T p.H1036Y | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782447630, COSV58442026; called by muse, mutect2, varscan2
- ATXN7L3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV66988489, COSV66988637; called by muse, mutect2, varscan2
- AUTS2 | c.3256C>T p.R1086W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61416503; called by muse, mutect2, varscan2
- BAG6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV99277524; called by muse, mutect2
- BIRC6 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV70195243; called by muse, mutect2, varscan2
- BRCA1 | c.5155G>A p.V1719M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV58783618; called by muse, varscan2
- BRD9 | c.402C>G p.A134= | Splice Region (SNP) | VAF 13/79 reads (16%) | catalogued as COSV51319209, COSV51319691; called by muse, mutect2, varscan2
- C2CD2 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111648364, COSV61598672; called by muse, mutect2, varscan2
- C6orf120 | c.257A>C p.H86P | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV59320891; called by muse, mutect2, varscan2
- C9orf64 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.225); catalogued as rs1201559259, COSV59032061; called by muse, mutect2, varscan2
- CACHD1 | c.1553T>C p.M518T | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs761527618, COSV51547601; called by muse, mutect2, varscan2
- CACNA1C | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.416); catalogued as rs1460962311, COSV59782518, COSV59782903; called by muse, mutect2
- CAMK1 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs578157926, COSV56537560; called by muse, mutect2, varscan2
- CAND1 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV73338529; called by muse, mutect2, varscan2
- CCDC8 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as rs753849206, COSV100282150; called by muse, varscan2
- CCNF | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769537532, COSV53537583; called by muse, mutect2, varscan2
- CDH17 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV99217930; called by muse, mutect2, varscan2
- CDH19 | c.1933G>A p.G645R | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50954215; called by muse, mutect2, varscan2
- CDK12 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV70999108, COSV71000848; called by muse, mutect2, varscan2
- CENPE | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV54375669; called by muse, mutect2, varscan2
- CFAP157 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs765229107, COSV58851930; called by muse, mutect2, varscan2
- CFAP36 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as rs1240757099, COSV59116496; called by muse, mutect2, varscan2
- CHRNA9 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV59574726; called by muse, mutect2, varscan2
- CLCN5 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs151340628, CM970316, COSV56582155; called by muse, mutect2, varscan2
- CLEC16A | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs74163622; called by muse, mutect2, varscan2
- CMYA5 | c.778A>G p.R260G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV71404039; called by muse, mutect2, varscan2
- COX15 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV50011855; called by muse, mutect2, varscan2
- CRTAM | c.1051+1G>A p.X351_splice | Splice Site (SNP) | VAF 21/27 reads (78%) | catalogued as COSV57066332, COSV57070597; called by muse, mutect2, varscan2
- CSN2 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61991730; called by muse, mutect2, varscan2
- CWC27 | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66883849; called by muse, varscan2
- CYP27A1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs777527880, COSV99298395; called by muse, mutect2, varscan2
- CYTH1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs770661079, COSV63118254; called by muse, mutect2, varscan2
- DCAF12 | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV63511507; called by muse, mutect2, varscan2
- DHDH | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55481230; called by muse, mutect2, varscan2
- DHX37 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756319573, COSV58131552; called by muse, mutect2, varscan2
- DIAPH1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV53878112; called by muse, mutect2, varscan2
- DLG2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV54619335; called by muse, mutect2, varscan2
- DNM1 | c.1321_1329del p.Q441_T443del | In Frame Del (DEL) | VAF 17/84 reads (20%) | catalogued as COSV57848604; called by mutect2, pindel, varscan2
- DNM2 | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV58956798; called by muse, mutect2, varscan2
- ECM1 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs976016653, COSV60871570; called by muse, mutect2, varscan2
- EFCC1 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs992938176, COSV71401743; called by muse, mutect2, varscan2
- EIF3E | c.128A>C p.D43A | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.088); catalogued as COSV55201276; called by muse, mutect2, varscan2
- EIF3L | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as COSV67739307; called by muse, mutect2, varscan2
- EIF5A | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59746794; called by muse, mutect2, varscan2
- ENOPH1 | c.85-1G>A p.X29_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56732073, COSV99908793; called by muse, mutect2, varscan2
- EPHA2 | c.1858G>C p.G620R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626147, COSV64452014; called by muse, mutect2, varscan2
- ETV4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60043670; called by muse, mutect2, varscan2
- EXPH5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV56198477, COSV56198612; called by muse, mutect2, varscan2
- EYA3 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65815353; called by muse, mutect2, varscan2
- F11 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs775238398, COSV53004045; called by muse, mutect2, varscan2
- FBN1 | c.4549T>C p.F1517L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV57308563; called by muse, mutect2, varscan2
- FEZF1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV58658133; called by muse, mutect2, varscan2
- FGD6 | c.1973_1974del p.T658Nfs*13 | Frame Shift Del (DEL) | VAF 47/105 reads (45%) | catalogued as COSV59690091; called by mutect2, pindel, varscan2
- FGL2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV50380136; called by muse, mutect2, varscan2
- FLCN | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV53256850; called by muse, mutect2, varscan2
- FN1 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100118060; called by muse, mutect2, varscan2
- FRRS1L | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV73746344; called by muse, mutect2, varscan2
- GAB2 | c.1492G>A p.V498M (on ENST00000361507 / NM_080491.3; = p.V460M on NM_012296.3) | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs781759827, COSV60865835; called by muse, mutect2, varscan2
- GABRA4 | c.1156A>G p.M386V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51921969; called by muse, mutect2, varscan2
- GDPD3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53771061; called by muse, mutect2, varscan2
- GJA4 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1283974059, COSV60724509; called by muse, mutect2, varscan2
- GJD4 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as rs1225032062, COSV58701865; called by muse, mutect2, varscan2
- GNAQ | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54106400, COSV54127986; called by muse, mutect2, varscan2
- GPCPD1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1473532289, COSV66830077; called by muse, mutect2, varscan2
- GTF3C1 | c.1716C>G p.D572E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs762709844, COSV62238759; called by muse, mutect2, varscan2
- GYG1 | c.902C>A p.S301* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as COSV99936940; called by muse, mutect2, varscan2
- HDHD3 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs766926828, COSV53056516; called by muse, mutect2, varscan2
- HECW1 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1369793479, COSV67821067; called by muse, mutect2, varscan2
- HLCS | c.1799G>A p.C600Y | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV60791149; called by muse, mutect2, varscan2
- HOXD1 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs992649739, COSV58922898; called by muse, mutect2, varscan2
- HPS3 | c.2023T>G p.L675V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as COSV56052475; called by muse, mutect2, varscan2
- HPSE | c.1422A>T p.Q474H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60985387; called by muse, mutect2, varscan2
- HTRA2 | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV51206059; called by muse, mutect2, varscan2
- HTT | c.7858C>A p.H2620N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV61857087; called by muse, mutect2, varscan2
- IDH1 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV61615873, COSV61637058; called by muse, mutect2, varscan2
- IFNA10 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV53330411; called by muse, varscan2
- IFT172 | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV53129270; called by muse, mutect2, varscan2
- IGFBPL1 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66617734; called by muse, mutect2, varscan2
- IGSF1 | c.1644C>T p.I548= | Splice Region (SNP) | VAF 52/141 reads (37%) | catalogued as rs1442573761, COSV63835868; called by muse, mutect2, varscan2
- INF2 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53029441; called by muse, mutect2
- INSYN2A | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs757299305, COSV54728925; called by muse, mutect2, varscan2
- IREB2 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV51920401; called by muse, mutect2, varscan2
- JAK1 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs761801070, COSV100692283; called by muse, varscan2
- KCNA10 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); catalogued as COSV63904172; called by muse, mutect2, varscan2
- KDM3A | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs762229054, COSV57217799, COSV57223589; called by muse, mutect2, varscan2
- KDM5A | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66990191; called by muse, mutect2, varscan2
- KLHDC7A | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs1411504949, COSV68768914; called by muse, mutect2, varscan2
- LAMA1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 45/115 reads (39%) | catalogued as rs1159839133, COSV101057501; called by muse, mutect2, varscan2
- LRRC37A3 | c.3917G>C p.R1306P | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.418); catalogued as rs764013252, COSV58534186, COSV58534207; called by muse, mutect2, varscan2
- MAGEE1 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV63908735, COSV63910032; called by muse, mutect2, varscan2
- MAP10 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101406546; called by muse, mutect2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MDGA1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51791516; called by muse, mutect2, varscan2
- MED13L | c.3035A>G p.Y1012C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs377437927; called by muse, varscan2
- MET | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1167093562, COSV59256432; called by muse, mutect2, varscan2
- MGA | c.8125G>T p.G2709C (on ENST00000219905 / NM_001164273.1; = p.G2500C on NM_001080541.2) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV54948077; called by muse, mutect2, varscan2
- MGA | c.8866G>T p.A2956S (on ENST00000219905 / NM_001164273.1; = p.A2747S on NM_001080541.2) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV54948088; called by muse, mutect2, varscan2
- MGAT5B | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV56924678; called by muse, mutect2, varscan2
- MKI67 | c.1982G>A p.W661* | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | catalogued as COSV100896923; called by muse, mutect2, varscan2
- MROH9 | c.24A>G p.T8= | Splice Region (SNP) | VAF 11/50 reads (22%) | catalogued as COSV63009592; called by muse, mutect2, varscan2
- MUC16 | c.38217C>A p.F12739L | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as rs375587590; called by muse, mutect2, varscan2
- MVB12B | c.540-2A>G p.X180_splice | Splice Site (SNP) | VAF 55/84 reads (65%) | catalogued as COSV63256207; called by muse, mutect2, varscan2
- MYH3 | c.2267A>T p.Q756L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV56860561, COSV99878833; called by muse, mutect2, varscan2
- NAIF1 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66089776; called by muse, mutect2, varscan2
- NCK1 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.067); catalogued as COSV56636000; called by muse, mutect2, varscan2
- NDRG4 | c.153C>A p.F51L (on ENST00000570248 / NM_001378344.1; = p.F83L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV50753061, COSV99262508; called by muse, mutect2, varscan2
- NDUFA10 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230530438, COSV53152467, COSV53155891; called by muse, mutect2, varscan2
- NDUFAF1 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV52974659; called by muse, mutect2, varscan2
- NEB | c.19828A>T p.T6610S | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50806746; called by muse, mutect2, varscan2
- NEURL4 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV59755914; called by muse, mutect2, varscan2
- NFE2L3 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs759527316, COSV50226138; called by muse, mutect2, varscan2
- NIPSNAP1 | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53341794, COSV99331156; called by muse, mutect2, varscan2
- NMRAL1 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52059085; called by muse, mutect2, varscan2
- NMRK2 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs764070326, COSV51454788; called by muse, mutect2, varscan2
- NPS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV67690466, COSV67690476; called by muse, mutect2, varscan2
- NUMA1 | c.4459G>A p.A1487T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.922); catalogued as COSV61182915; called by muse, mutect2, varscan2
- NUP98 | c.2739C>G p.S913R | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as rs753648794, COSV61428188; called by muse, mutect2, varscan2
- NUTM1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs1289133378, COSV61545794; called by muse, mutect2, varscan2
- OCA2 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772019064, CM085601, CM100992, COSV62337789, COSV62353533; called by muse, mutect2, varscan2
- OR2S2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59529195; called by muse, mutect2, varscan2
- OR52A5 | c.29T>C p.M10T | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV56614088; called by muse, mutect2, varscan2
- OR9Q1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV59036289; called by muse, mutect2, varscan2
- ORC1 | c.1876T>A p.W626R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65363253; called by muse, mutect2, varscan2
- OSCAR | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs200068810; called by muse, mutect2, varscan2
- OTOGL | c.3537T>G p.S1179R (on ENST00000547103; = p.S1170R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV72005561; called by muse, mutect2, varscan2
- PAK2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.149); catalogued as rs776632073, COSV59078989; called by muse, mutect2, varscan2
- PALMD | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); catalogued as COSV54162629; called by muse, mutect2, varscan2
- PARP1 | c.2711G>C p.S904T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64689061; called by muse, mutect2, varscan2
- PCDHB14 | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as rs1297186534, COSV53386329; called by muse, mutect2, varscan2
- PCDHB6 | c.1853A>G p.H618R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV50689564; called by muse, mutect2, varscan2
- PCSK6 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246087840, COSV59338006; called by muse, mutect2, varscan2
- PDSS2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1267747373, COSV64646324; called by muse, mutect2, varscan2
- PELO | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99252016; called by muse, mutect2, varscan2
- PEX12 | c.1037C>A p.T346K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV56777482; called by muse, mutect2, varscan2
- PIGV | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50290345; called by muse, mutect2, varscan2
- PKHD1 | c.7911+2T>C p.X2637_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as rs1376949476, COSV61859302; called by muse, mutect2, varscan2
- PLCD3 | c.1948T>C p.F650L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99364955; called by muse, mutect2
- PLEC | c.894G>C p.K298N (on ENST00000322810 / NM_201380.4; = p.K188N on NM_000445.5) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59601312; called by muse, mutect2, varscan2
- PNN | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.452); catalogued as rs748138901, COSV53765310; called by muse, mutect2, varscan2
- PNPLA7 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs142091055; called by muse, mutect2, varscan2
- PRKCA | c.1410G>C p.M470I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV52577537; called by muse, mutect2, varscan2
- PSAP | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1165032545, COSV67549668; called by muse, mutect2, varscan2
- PYGB | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as rs200006792, COSV53815422; called by muse, mutect2, varscan2
- RAB29 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.5); PolyPhen benign (0.173); catalogued as COSV52520652; called by muse, mutect2, varscan2
- RAD51AP2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV67587258; called by muse, mutect2, varscan2
- RALGAPA2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV52486846; called by muse, mutect2, varscan2
- RANBP2 | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV51695898; called by muse, mutect2, varscan2
- RAPH1 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57350538; called by muse, mutect2, varscan2
- RBAK | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.992); catalogued as COSV62330741; called by muse, mutect2, varscan2
- RBBP7 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV66300275; called by muse, mutect2
- RBBP7 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV66300281; called by muse, mutect2, varscan2
- RBM15B | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs782316104, COSV60371035; called by muse, mutect2, varscan2
- REV1 | c.850A>G p.R284G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51481594; called by muse, mutect2, varscan2
- RGS12 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV60901944; called by muse, mutect2, varscan2
- RGS9 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV52222760; called by muse, mutect2, varscan2
- RNASEL | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 64/101 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62376159; called by muse, mutect2, varscan2
- RNF20 | c.333T>A p.Y111* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100874336; called by muse, mutect2, varscan2
- RNF213 | c.2197C>A p.Q733K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100173881; called by muse, mutect2, varscan2
- RPAP2 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV72509129; called by muse, mutect2, varscan2
- RPRD2 | c.846C>A p.Y282* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as rs1553895502, COSV100954742; called by muse, mutect2, varscan2
- RRAGB | c.386C>T p.T129I (on ENST00000262850 / NM_016656.4; = p.T101I on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99469591; called by muse, mutect2
- SCAND1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100018926; called by muse, mutect2, varscan2
- SDC3 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV100232532, COSV59578303; called by muse, varscan2
- SENP7 | c.2729C>G p.S910C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV58607411; called by muse, mutect2, varscan2
- SEZ6L | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV50657709, COSV50657985; called by muse, mutect2, varscan2
- SHROOM2 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV66604346; called by muse, mutect2, varscan2
- SIRT1 | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53016853; called by muse, mutect2, varscan2
- SLC12A5 | c.932T>G p.L311R (on ENST00000454036 / NM_001134771.2; = p.L288R on NM_020708.5) | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as CM159457, COSV54787677; called by muse, mutect2, varscan2
- SLC22A23 | c.1633A>T p.M545L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.807); catalogued as COSV100978370; called by muse, mutect2, varscan2
- SLC22A4 | c.1195T>G p.Y399D | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV52356670; called by muse, mutect2, varscan2
- SLC45A1 | c.1855G>C p.G619R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57092744; called by muse, mutect2, varscan2
- SLCO3A1 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59224407; called by muse, mutect2, varscan2
- SMARCA1 | c.1815+1_1815+15del p.X605_splice | Splice Site (DEL) | VAF 28/96 reads (29%) | catalogued as COSV64410700; called by mutect2, pindel, varscan2
- SMG5 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV62433880; called by muse, mutect2, varscan2
- SPANXN3 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV65139934; called by muse, mutect2, varscan2
- SPIN3 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as COSV66528909; called by muse, mutect2, varscan2
- STIL | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV54547396; called by muse, mutect2, varscan2
- STPG4 | c.452A>T p.K151I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV54277782, COSV99681369; called by muse, mutect2, varscan2
- STXBP3 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs1258802736, COSV64181500; called by muse, mutect2, varscan2
- SULT1E1 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775733144, COSV56946000; called by muse, mutect2, varscan2
- SYNE2 | c.20378C>T p.S6793F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV59938816; called by muse, varscan2
- SYNPO2 | c.3679A>G p.R1227G | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs1321917322, COSV61105927; called by muse, mutect2, varscan2
- TACC2 | c.4073G>A p.S1358N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV57745349; called by muse, mutect2, varscan2
- TACR2 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV64821781; called by muse, mutect2, varscan2
- TCTN2 | c.1283G>A p.G428D | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs1352735139, COSV57631494; called by muse, mutect2, varscan2
- TEP1 | c.7534C>G p.P2512A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV52987723, COSV52994966; called by muse, mutect2, varscan2
- TFAP2A | c.677C>A p.T226N (on ENST00000482890; = p.T218N on NM_001032280.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100117145; called by muse, mutect2
- TFAP2B | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53824874; called by muse, mutect2, varscan2
- TG | c.3263G>T p.S1088I | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV55064346; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2443A>G p.K815E | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV51509782; called by muse, mutect2, varscan2
- TIAL1 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV64842954; called by muse, mutect2, varscan2
- TM9SF3 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1423040459, COSV64456516; called by muse, mutect2, varscan2
- TMC6 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV59208467; called by muse, mutect2, varscan2
- TMCO5A | c.445-2A>T p.X149_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60463906; called by muse, varscan2
- TMEM187 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs782745092, COSV64141120; called by muse, mutect2, varscan2
- TMEM26 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.097); catalogued as rs752801982, COSV67492510; called by muse, mutect2, varscan2
- TMEM80 | c.313C>G p.L105V (on ENST00000526170 / NM_001276274.1; = p.L167V on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV59346721; called by muse, mutect2, varscan2
- TNIP2 | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59568817; called by muse, mutect2, varscan2
- TNPO3 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1429759493, COSV55277532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAF3IP2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs758695030, COSV60674990; called by muse, mutect2, varscan2
- TRIM39 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.086); catalogued as COSV64954864; called by muse, mutect2, varscan2
- TRIO | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV60077091; called by muse, mutect2, varscan2
- TRPM1 | c.1507-1G>A p.X503_splice | Splice Site (SNP) | VAF 34/75 reads (45%) | catalogued as COSV56630027; called by muse, mutect2, varscan2
- TRPM6 | c.4958G>A p.C1653Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1255331712, COSV62502310; called by muse, mutect2, varscan2
- TSC2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767626323, COSV54592170; called by mutect2, varscan2
- TSPOAP1 | c.3596G>A p.C1199Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV52103679; called by muse, varscan2
- TXK | c.1223A>G p.D408G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51912266; called by muse, mutect2, varscan2
- UBIAD1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs928829812, COSV65147474; called by muse, mutect2, varscan2
- UBQLN2 | c.711T>G p.I237M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV57738969; called by muse, mutect2, varscan2
- UBXN6 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV56670055; called by muse, mutect2, varscan2
- UNC119B | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60865671; called by muse, mutect2, varscan2
- UQCRFS1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59184293; called by muse, mutect2, varscan2
- USP8 | c.1219A>T p.I407F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100209241; called by muse, mutect2, varscan2
- VPS33A | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV57355883; called by muse, mutect2, varscan2
- VPS37A | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61352480; called by muse, mutect2, varscan2
- VPS54 | c.252A>C p.K84N | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV55437151; called by muse, mutect2, varscan2
- WASHC2C | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as COSV60490002; called by muse, mutect2, varscan2
- WDR91 | c.967T>A p.S323T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV60368480; called by muse, mutect2, varscan2
- WNT7A | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs1216538333, COSV53196582; called by muse, mutect2, varscan2
- XRRA1 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 39/58 reads (67%) | catalogued as COSV100370055; called by muse, mutect2, varscan2
- ZFAND2B | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305153109, COSV54692569; called by muse, mutect2, varscan2
- ZFP36L1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60544219; called by muse, mutect2
- ZNF107 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV61326658; called by muse, mutect2, varscan2
- ZNF276 | c.487G>A p.G163S (on ENST00000443381 / NM_001113525.2; = p.G88S on NM_152287.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as rs748405201, COSV57065622; called by muse, mutect2, varscan2
- ZNF37A | c.613T>C p.C205R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs200021466, COSV61072378; called by muse, mutect2, varscan2
- AC242842.3 | c.24dup p.S9Vfs*3 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, varscan2
- AK4 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ANLN | c.2591_2603+30del p.X864_splice | Splice Site (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- CCDC180 | c.2025del p.K675Nfs*30 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- CWC22 | c.1579_1593del p.G527_E531del | In Frame Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, varscan2
- DOP1B | c.146_153dup p.L52Rfs*4 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- FBH1 | c.2201-10_2207del p.X734_splice (on ENST00000362091 / NM_178150.3; = p.X785_splice on NM_032807.4) | Splice Site (DEL) | VAF 54/107 reads (50%) | called by mutect2, pindel, varscan2
- FOS | c.1091_1093dup p.S364dup | In Frame Ins (INS) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- GFM2 | c.1748dup p.D584Rfs*16 | Frame Shift Ins (INS) | VAF 31/111 reads (28%) | called by mutect2, pindel, varscan2
- H2AC6 | c.372_389del p.H124_K130delinsQ | In Frame Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel
- IGHV6-1 | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PABPC1 | c.178del p.Q60Sfs*13 | Frame Shift Del (DEL) | VAF 38/70 reads (54%) | called by pindel, varscan2
- RIN2 | c.879_911del p.C293_R304delinsW (on ENST00000255006 / NM_001242581.1; = p.C244_R255delinsW on NM_018993.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- SHH | c.767_777del p.E256Afs*63 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- SMG8 | c.209_214del p.T70_C72delinsS | In Frame Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- SYNRG | c.2323G>T p.D775Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.482_500del p.A161Gfs*3 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- TPR | c.340_350del p.T114Gfs*6 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, varscan2
- TUBGCP3 | c.973del p.C325Vfs*24 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- ACP3 | c.945G>A p.L315= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1036731217, COSV60484437; called by muse, mutect2, varscan2
- ACSS3 | c.1569C>T p.F523= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV54084170; called by muse, mutect2, varscan2
- AFF2 | c.1614A>G p.T538= | Silent (SNP) | VAF 80/229 reads (35%) | catalogued as COSV53975425; called by muse, mutect2, varscan2
- ANKAR | c.2542C>A p.R848= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as rs755839623, COSV55609206, COSV99853918; called by muse, mutect2, varscan2
- ANKFN1 | c.1146G>A p.K382= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs972730205, COSV59440154; called by muse, mutect2, varscan2
- ASB16 | c.111G>A p.R37= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53233917; called by muse, mutect2
- ATXN3L | c.291T>A p.P97= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV66075200; called by muse, mutect2, varscan2
- BBS10 | c.117G>A p.T39= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV53877722; called by muse, mutect2, varscan2
- BCR | c.1731G>C p.V577= | Silent (SNP) | VAF 32/48 reads (67%) | catalogued as COSV59926176; called by muse, mutect2, varscan2
- C1orf56 | c.528C>T p.S176= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1255638006, COSV54845643; called by muse, mutect2, varscan2
- C4BPA | c.1392G>A p.A464= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs754383771, COSV65535625; called by mutect2, varscan2
- CACNA1S | c.2811C>T p.L937= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV62935775; called by muse, mutect2, varscan2
- CATSPER3 | c.258G>A p.S86= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs753785477, COSV50945195; called by muse, mutect2, varscan2
- CCDC138 | c.1977G>A p.L659= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs199651386, COSV54564132; called by muse, mutect2, varscan2
- CCDC157 | c.2058C>T p.C686= | Silent (SNP) | VAF 94/173 reads (54%) | catalogued as COSV53175322, COSV99306386; called by muse, varscan2
- CRTAC1 | c.1089C>T p.F363= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs753762714, COSV53996614; called by muse, varscan2
- DDX10 | c.435C>T p.L145= | Silent (SNP) | VAF 44/65 reads (68%) | catalogued as rs1240571358, COSV59431284; called by muse, mutect2, varscan2
- DOCK9 | c.4156C>T p.L1386= (on ENST00000376460 / NM_001366676.2; = p.L1387= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV59619050; called by muse, mutect2, varscan2
- DOP1B | c.660G>T p.L220= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV67695054; called by muse, mutect2
- EEA1 | c.3441C>T p.L1147= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs1244951912, COSV59282246; called by muse, mutect2, varscan2
- ENKUR | c.39C>T p.L13= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV58632246; called by muse, mutect2, varscan2
- EPHB3 | c.819C>T p.T273= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs570166840, COSV57804053; called by muse, mutect2, varscan2
- EPHB6 | c.2661T>C p.C887= | Silent (SNP) | VAF 70/163 reads (43%) | catalogued as COSV63890300; called by muse, mutect2, varscan2
- ERCC3 | c.1641G>C p.L547= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV53425391; called by muse, mutect2, varscan2
- EXOC2 | c.540T>C p.F180= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV57860869; called by muse, mutect2, varscan2
- FANCA | c.2625G>A p.L875= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV59795309; called by muse, mutect2, varscan2
- FLNA | c.5262T>G p.S1754= (on ENST00000369850 / NM_001110556.2; = p.S1746= on NM_001456.3) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100775119; called by muse, mutect2, varscan2
- GIMAP5 | c.216A>G p.T72= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV57529607; called by muse, mutect2, varscan2
- GPR21 | c.579G>T p.L193= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs1182256123, COSV65378787, COSV65379095; called by muse, mutect2, varscan2
- H2BC8 | c.273C>T p.T91= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as COSV55126087; called by muse, mutect2
- HECTD1 | c.7657C>T p.L2553= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV67944953, COSV67946409; called by muse, mutect2, varscan2
- HMGCS1 | c.823C>T p.L275= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV57289259; called by muse, mutect2, varscan2
- ITGAD | c.3213A>G p.T1071= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99791462; called by muse, mutect2, varscan2
- JAK2 | c.393C>T p.A131= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV67571885; called by muse, mutect2, varscan2
- KHDC4 | c.1662G>A p.K554= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV64166229; called by muse, mutect2, varscan2
- KLK1 | c.417C>T p.V139= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs764872324, COSV56825790; called by muse, mutect2, varscan2
- LDB3 | c.318G>A p.Q106= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs760617777, COSV99555807; ClinVar: likely benign; called by muse, varscan2
- LRRTM3 | c.1191G>A p.P397= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1339003025, COSV63660750; called by muse, mutect2, varscan2
- MAMDC4 | c.2547C>T p.T849= (on ENST00000445819; = p.T770= on NM_206920.3) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56374628, COSV99808257; called by muse, mutect2, varscan2
- MAP3K8 | c.879C>T p.Y293= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1439549207, COSV53918621; called by muse, mutect2, varscan2
- MEOX1 | c.495G>A p.P165= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs773733434, COSV59355149; called by muse, varscan2
- MKS1 | c.924A>C p.P308= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58302510; called by mutect2, varscan2
- NAALAD2 | c.285A>G p.L95= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV58958441; called by muse, mutect2, varscan2
- NPTN | c.1083G>A p.E361= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs1566959219, COSV54736599; called by muse, mutect2, varscan2
- NVL | c.568C>T p.L190= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as rs1193834293, COSV55869896; called by muse, mutect2, varscan2
- OPN1SW | c.525C>T p.F175= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV50821194; called by muse, mutect2, varscan2
- PAN2 | c.1209C>T p.T403= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV57752550; called by muse, mutect2, varscan2
- PANK1 | c.63T>C p.S21= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1398704801, COSV100285781; called by muse, mutect2, varscan2
- PLEKHG6 | c.921C>T p.I307= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV50598188; called by muse, mutect2, varscan2
- PPP1R3A | c.384A>C p.A128= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV52875513; called by muse, mutect2, varscan2
- PRKAR1B | c.261G>A p.P87= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs545804273, COSV64317682; called by muse, mutect2, varscan2
- RABGGTA | c.435C>T p.C145= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV53769293; called by muse, mutect2, varscan2
- RAD54B | c.2565A>T p.P855= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV60249379, COSV60255680; called by muse, mutect2, varscan2
- RBPJL | c.102C>T p.D34= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs533358769, COSV59212560; called by muse, mutect2, varscan2
- SEPHS2 | c.621G>A p.G207= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV101529330, COSV72100701; called by muse, mutect2, varscan2
- SESN1 | c.1311C>T p.I437= (on ENST00000356644 / NM_001199933.1; = p.I496= on NM_014454.3) | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV57420212; called by muse, mutect2, varscan2
- SIM2 | c.9G>A p.E3= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV51765815; called by muse, mutect2, varscan2
- SLC35D1 | c.99G>C p.S33= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52429582; called by muse, mutect2, varscan2
- SLC38A3 | c.1003C>T p.L335= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as COSV68843876; called by muse, mutect2, varscan2
- SRP54 | c.1335C>T p.D445= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1486295735, COSV53738290; called by muse, mutect2, varscan2
- STARD7 | c.1021C>T p.L341= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs756746674, COSV61525047; called by muse, mutect2, varscan2
- TASOR | c.3447C>T p.S1149= (on ENST00000355628 / NM_001365636.2; = p.S773= on NM_015224.3) | Silent (SNP) | VAF 102/128 reads (80%) | catalogued as rs1342446843, COSV62926676; called by muse, mutect2, varscan2
- TET1 | c.1671C>T p.V557= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs1225853547, COSV65381781; called by muse, mutect2, varscan2
- TLE1 | c.286C>T p.L96= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV64685475; called by muse, mutect2, varscan2
- TLR4 | c.1191G>T p.G397= (on ENST00000355622 / NM_138554.5; = p.G357= on NM_003266.4) | Silent (SNP) | VAF 67/115 reads (58%) | catalogued as COSV62922355, COSV62924211; called by muse, mutect2, varscan2
- TMEM241 | c.618C>T p.V206= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs750860331, COSV67242830; called by muse, mutect2, varscan2
- TMEM63C | c.774C>T p.D258= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs777902189, COSV53600948; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.444C>T p.L148= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV59528037; called by muse, mutect2, varscan2
- TNRC6B | c.711T>C p.S237= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV57288025; called by muse, mutect2, varscan2
- TRAV1-2 | c.9A>T p.G3= | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- TRIL | c.81C>T p.C27= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1354027415, COSV59866516; called by muse, mutect2, varscan2
- TRMT10B | c.948A>G p.E316= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV53049593; called by muse, mutect2
- UNG | c.198G>A p.L66= (on ENST00000242576 / NM_080911.3; = p.L57= on NM_003362.4) | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs781147313, COSV54356156, COSV99655198; called by muse, mutect2, varscan2
- USP9X | c.2763T>C p.N921= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV61065502; called by muse, mutect2, varscan2
- VPS13D | c.11334C>T p.I3778= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV50621310; called by muse, mutect2, varscan2
- WRNIP1 | c.1137G>A p.K379= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV66355736; called by muse, mutect2, varscan2
- YTHDC2 | c.141C>T p.I47= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1164887836, COSV50736449; called by muse, mutect2, varscan2
- ZNF287 | c.2025C>T p.P675= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV101209364, COSV67688076; called by muse, mutect2, varscan2
- ZNF354C | c.1011C>T p.F337= | Silent (SNP) | VAF 76/178 reads (43%) | catalogued as COSV59607049; called by muse, mutect2, varscan2
- ZNF687 | c.1882C>T p.L628= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV55014756; called by muse, mutect2, varscan2
- ZNF808 | c.888C>T p.F296= | Silent (SNP) | VAF 67/94 reads (71%) | catalogued as COSV63118558; called by muse, mutect2, varscan2
- ZNF98 | c.108T>C p.N36= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as rs1445376750, COSV63334052; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851393 G>A | 3'Flank (SNP) | VAF 90/216 reads (42%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501920 T>C | 5'Flank (SNP) | VAF 14/42 reads (33%) | catalogued as rs1035168626; called by muse, mutect2, varscan2
- C6orf223 | n.385C>G | RNA (SNP) | VAF 9/14 reads (64%) | catalogued as rs748887170, COSV100350531; called by muse, varscan2
- ECPAS | chr9:111484360 G>A | 5'Flank (SNP) | VAF 5/24 reads (21%) | catalogued as rs1267496007, COSV99399117; called by muse, mutect2
- GREB1 | c.1160-1340T>A | Intron (SNP) | VAF 34/70 reads (49%) | catalogued as COSV52179804; called by muse, mutect2, varscan2
- HHIPL1 | c.1730+563C>T | Intron (SNP) | VAF 20/42 reads (48%) | catalogued as COSV58088954; called by muse, mutect2, varscan2
- MGAT4B | c.98-97C>T | Intron (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99482376; called by muse, mutect2, varscan2
- MIR148A | n.49_50dup | RNA (INS) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- TMEM164 | c.391-11984G>T | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99912037; called by muse, mutect2, varscan2
- TTN | c.10303+2550G>C | Intron (SNP) | VAF 13/37 reads (35%) | catalogued as COSV59871367; called by muse, mutect2, varscan2
